HCMI case HCM-CSHL-0186-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/387a6f37-fe35-4ffc-a4b3-dda1af08f6c3

Demographics
Sex at birth: male; Year of birth: 1944.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 74.2 years (27,102 days); AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 62.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 277, day 675.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: -51 days; Diabetes treatment type: Diet.
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 173 cm; BMI: 31.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol intensity: Drinker; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0186-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0186-C25-01A-02-S1-HE: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 78; Percent lymphocyte infiltration: 38; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0186-C25-01A-02-S2-HE: Section location: Bottom; Percent tumor cells: 13; Percent tumor nuclei: 18; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 86; Percent lymphocyte infiltration: 75; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0186-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0186-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
